Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6522, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6522-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Partial resection of organ - stomach

TCGA - D7 - 6522

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the stomach. Neoplastic ulceration – gastric body, parapyloric region.

Examination performed on:

Macroscopic description:

Sent material consisting of the parapyloric part and stomach body, cut out along the greater curvature, sized 17.7 x 11.2 cm with the omentum sized 33 x 13 cm. Tumour in the parapyloric region sized 3.3 x 4.6 x 0.7 cm. Distance from the proximal end 4 cm, from distal end 2.5 cm.

Histopathological diagnosis:

Adenocarcinoma mucocellulare ventriculi (invasive type s. Lauren; G3) - infiltratio parietis partim ventriculi - pT2). Mucocellular adenocarcinoma of the stomach (invasive type s. Lauren; G3) - partial infiltration of the stomach wall.

Incision lines free of neoplastic lesions

Lymph nodes:

Lymphonodulitis reactiva No. XI (pN0). Reactive inflammation of the lymph nodes No. XI (pN0)

CALL YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 767159c2-d6ee-4eaa-a163-398617607ef8 (TCGA-D7-6522.B0DEE176-8E1D-4ECE-ADEA-157C5B8FDBEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).